Somatic mutation profile of tumor specimen 0DWGJV from CCDI case PBCNFU, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Papillary carcinoma, NOS; Tissue or organ of origin: Thyroid gland; Age at diagnosis: 10.4 years (3,781 days).
Specimen 0DWGJV: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7f412049-4725-422e-b7d6-bcfc74f261ec.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DWGJ0 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/15bca23a-1c15-4d45-baf0-dd9c319ea344

The open-access MAF lists 3 somatic variants for this specimen: 1 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: RNA 1, Missense Mutation 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- POLRMT | c.2029G>A p.A677T | Missense Mutation (SNP) | VAF 113/322 reads (35%) | SIFT tolerated (0.74); PolyPhen benign (0.014); catalogued as rs767782097; called by muse, mutect2, varscan2
- RBL1 | c.-51A>C | 5'UTR (SNP) | VAF 67/183 reads (37%) | catalogued as rs1469745174; called by muse, mutect2, varscan2
- VENTXP7 | n.58G>A | RNA (SNP) | VAF 83/432 reads (19%) | catalogued as rs1469268760; called by muse, mutect2, varscan2
